Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5KX, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5KX-01A (Primary Tumor).

ICD-0-3

Carcinoma, adrenal
cortical 8370/3
Site: Adrenal Gland
Cortex C74.0
2/6/13

Procedure: adrenalectomy and nephrectomy

Gross description: 25 x 17 x 8.5cm with 18cm tumor

Reference Pathology only:

Diagnosis: adrenocortical carcinoma, KI67 10%

Weiss score: 7

Hough score: 5.58

Van Slooten score: 22.7

Criteria	W 1/12/13	Yes	No
MRI AA Discrepancy			

Source: NCI Genomic Data Commons file f236a744-c993-4239-bcca-bda04a32c88e (TCGA-OR-A5KX.02EBE0C2-AE20-4F08-81E7-3EC45E12C0F4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).